Somatic mutation profile of tumor specimen TCGA-13-A5FT-01A (aliquot TCGA-13-A5FT-01A-11D-A403-09) from TCGA case TCGA-13-A5FT, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,743 days).
Specimen TCGA-13-A5FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b30f800-d275-477c-9c5e-beb6bbaa5577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-A5FT-10A (Blood Derived Normal), aliquot TCGA-13-A5FT-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/433ac8bc-37bf-423a-8256-9d06fca4424f

The open-access MAF lists 80 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 12, Frame Shift Del 5, Frame Shift Ins 3, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV99710357; called by muse, mutect2, varscan2
- ADGRF4 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs147067379, COSV51949224; called by muse, mutect2, varscan2
- AMER3 | c.585del p.R196Gfs*70 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | catalogued as COSV58470642; called by mutect2, pindel, varscan2
- ASB17 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99407923; called by muse, mutect2, varscan2
- CA4 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766918079, COSV56283473; called by muse, mutect2, varscan2
- CAPZA3 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as rs767377385, COSV99856306; called by muse, mutect2, varscan2
- CDYL | c.1007A>G p.E336G (on ENST00000328908 / NM_001368125.1; = p.E282G on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100189259; called by muse, mutect2, varscan2
- CEBPE | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.283); catalogued as COSV99247495; called by muse, mutect2, varscan2
- CENPF | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100871669; called by mutect2, varscan2
- CENPF | c.3368G>A p.S1123N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs759811640, COSV100871670; called by muse, mutect2, varscan2
- CTNNA2 | c.2243T>G p.I748S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560450; called by muse, mutect2, varscan2
- CUBN | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as COSV100912596, COSV64713135, COSV64727700; called by muse, mutect2, varscan2
- DNM1L | c.1308T>G p.H436Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99846035; called by muse, mutect2, varscan2
- DPP4 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149643982, COSV62106254; called by muse, mutect2, varscan2
- ERLEC1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | catalogued as COSV99483016; called by muse, mutect2, varscan2
- ETV7 | c.934G>T p.V312F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV100339183; called by muse, mutect2, varscan2
- FAM171A1 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs1463514984, COSV100968236; called by muse, mutect2, varscan2
- FLT1 | c.1350A>T p.Q450H | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99154239; called by muse, mutect2, varscan2
- GORASP1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100073089; called by muse, varscan2
- GRIN3B | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV99312472; called by muse, mutect2, varscan2
- GRIN3B | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52260131; called by muse, mutect2, varscan2
- HMCN1 | c.2022A>T p.K674N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99628605; called by muse, mutect2, varscan2
- ICE1 | c.1241G>C p.G414A | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV99664603; called by muse, mutect2, varscan2
- JADE3 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs1556365174, COSV99509827; called by muse, mutect2, varscan2
- KIAA1109 | c.5623G>T p.V1875F | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99160324; called by muse, mutect2, varscan2
- KIAA1217 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as rs1345469622, COSV100286566; called by muse, mutect2, varscan2
- KIF11 | c.1865A>G p.Q622R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as COSV99585818; called by muse, mutect2, varscan2
- LILRB1 | c.1807C>A p.P603T (on ENST00000427581; = p.P552T on NM_006669.6) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV100207255; called by muse, mutect2, varscan2
- LRRC41 | c.1015A>C p.K339Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.141); catalogued as COSV100586307; called by muse, mutect2, varscan2
- MACF1 | c.14377C>G p.L4793V (on ENST00000372915; = p.L2726V on NM_012090.5) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV99243922; called by muse, mutect2, varscan2
- MPP6 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV99757462; called by muse, mutect2, varscan2
- MUTYH | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs745424307, COSV100517320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYF5 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99953261; called by muse, mutect2, varscan2
- NBAS | c.5752A>T p.T1918S | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV99869275; called by muse, mutect2, varscan2
- NUP210L | c.2072dup p.L691Ffs*21 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | catalogued as rs760869296; called by mutect2, varscan2
- OR4A16 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1201820868, COSV100125202; called by muse, mutect2, varscan2
- OR5T2 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100506920; called by muse, mutect2, varscan2
- PADI2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100970922; called by muse, mutect2, varscan2
- PLPPR1 | c.252T>G p.I84M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV100883253; called by muse, mutect2, varscan2
- PYGL | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99368584; called by muse, mutect2, varscan2
- RGS3 | c.2972G>A p.G991D (on ENST00000350696 / NM_001282923.2; = p.G710D on NM_130795.4) | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100636706; called by muse, mutect2, varscan2
- RNF139 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV99413365; called by muse, mutect2, varscan2
- RP1 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as rs763287594, COSV99607321; called by muse, mutect2, varscan2
- RYR2 | c.9577G>A p.A3193T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as COSV100769879; called by muse, mutect2, varscan2
- SLC30A6 | c.1027T>C p.S343P | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99249602; called by muse, mutect2, varscan2
- SLC41A3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59990079; called by muse, mutect2, varscan2
- SPATA20 | c.1664G>C p.C555S (on ENST00000356488 / NM_001258372.1; = p.C571S on NM_022827.4) | Missense Mutation (SNP) | VAF 84/94 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV99135915; called by muse, mutect2, varscan2
- SSRP1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV99554891; called by muse, mutect2, varscan2
- TAFA3 | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100721467; called by muse, mutect2, varscan2
- TAP2 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV100886866; called by muse, mutect2, varscan2
- TP53 | c.430_431insT p.Q144Lfs*5 | Frame Shift Ins (INS) | VAF 12/22 reads (55%) | catalogued as COSV99037288; called by mutect2, pindel*, varscan2
- TRIM41 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1438006821, COSV100163229; called by muse, mutect2, varscan2
- TRPC5 | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99460688; called by muse, mutect2, varscan2
- TRUB2 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758941031, COSV100867803; called by muse, mutect2, varscan2
- TSPEAR | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV100553291; called by muse, mutect2, varscan2
- TTC21B | c.2446C>G p.L816V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV99692243; called by muse, mutect2, varscan2
- USP15 | c.2579A>G p.D860G (on ENST00000280377 / NM_001351159.2; = p.D831G on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV99739429; called by muse, mutect2
- VGLL3 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV101051912; called by muse, mutect2, varscan2
- VPS41 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100053860; called by muse, mutect2, varscan2
- CDH10 | c.633_646+26del p.X211_splice | Splice Site (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- CDKN1B | c.85_103del p.C29Rfs*7 | Frame Shift Del (DEL) | VAF 41/117 reads (35%) | called by mutect2, pindel, varscan2
- CENPF | c.178del p.T60Pfs*6 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, varscan2
- CPXCR1 | c.322_324del p.D108del | In Frame Del (DEL) | VAF 21/104 reads (20%) | called by mutect2, pindel, varscan2
- MED12L | c.3018_3019insGTCTG p.R1007Vfs*12 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | called by mutect2, pindel*, varscan2
- PCDHB9 | c.846del p.F282Lfs*8 | Frame Shift Del (DEL) | VAF 43/123 reads (35%) | called by mutect2, pindel, varscan2
- TNK2 | c.634_644del p.S212Pfs*4 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- TRAV21 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AHI1 | c.198T>C p.T66= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV99662624; called by muse, mutect2, varscan2
- ESX1 | c.159C>T p.Y53= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV101006434; called by muse, mutect2, varscan2
- HCAR2 | c.312C>G p.L104= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as COSV100186499; called by muse, mutect2, varscan2
- NOMO1 | c.1437G>A p.L479= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV99814499; called by muse, varscan2
- OCA2 | c.417G>A p.L139= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100667662; called by muse, mutect2, varscan2
- PADI2 | c.591A>G p.G197= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100970920; called by muse, mutect2, varscan2
- PGPEP1 | c.498C>T p.F166= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs146707720; called by muse, mutect2, varscan2
- POLR2A | c.5544C>G p.P1848= | Silent (SNP) | VAF 32/41 reads (78%) | called by muse, mutect2, varscan2
- SARDH | c.1101G>A p.R367= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100897944; called by muse, mutect2, varscan2
- SPATC1 | c.387A>G p.A129= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV101084935; called by muse, mutect2, varscan2
- TCEA3 | c.723C>G p.R241= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV101508308; called by muse, mutect2, varscan2
- TSGA10IP | c.498G>A p.A166= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs758851062, COSV101598404; called by muse, mutect2, varscan2
- CPLANE1 | c.*4171G>A | 3'UTR (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99950427; called by muse, mutect2, varscan2
